Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A8I6, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A8I6-01A (Primary Tumor).

[page 1 of 4]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) RIGHT OBTURATOR AND INTERNAL ILIAC LYMPH NODES:
Eleven lymph nodes, no tumor present.(0/11)
- (B) RIGHT EXTERNAL ILIAC LYMPH NODES:
Two lymph nodes, no tumor present.(0/2)
- (C) LEFT OBTURATOR AND INTERNAL ILIAC LYMPH NODES:
Ten lymph nodes, no tumor present.(0/10)
- (D) LEFT EXTERNAL ILIAC LYMPH NODES:
Fibroadipose tissue, no tumor or lymph nodes present.
- (E) LEFT BASE:
Supplemental report to follow.
- (F) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.

ICD6-3
~~Adenocarcinoma~~, acinar 8/40/13
~~Adenocarcinoma~~ NOS 8/40/13
Site Prostate NOS C61.9
JW 11/24/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) RIGHT OBTURATOR AND INTERNAL ILIAC LYMPH NODES – Received is a 3.5 x 2.2 x 1.2 cm fragment of adipose tissue from which eleven possible lymph nodes are identified ranging in size from 0.5 to 1.4 cm, grossly unremarkable.
SECTION CODE: A1, five lymph nodes, per cassette; A2, three lymph nodes, per cassette; A3, three lymph nodes, per cassette.
- (B) RIGHT EXTERNAL ILIAC LYMPH NODES – Received is a 1.5 x 1.2 x 0.5 cm fatty fragment with four possible lymph nodes ranging in size from 0.5 to 0.7 cm which are grossly unremarkable.
SECTION CODE: B1, four possible lymph nodes; B2, remaining fat, entirely submitted.
- (C) LEFT OBTURATOR AND INTERNAL ILIAC LYMPH NODES – Received is a 5.5 x 3.8 x 1.2 cm fragment of adipose tissue from which ten possible lymph nodes are identified. The smallest one measures 0.5 x 0.5 x 0.2 cm. The largest lymph node is fatty and is 5.5 x 1.2 x 1 cm.
SECTION CODE: C1, five lymph nodes, per cassette; C2, four lymph nodes, per cassette; C3-C5, one large fatty lymph node, entirely submitted.
- (D) LEFT EXTERNAL ILIAC LYMPH NODES – A single portion of brown-yellow fibroadipose tissue (2 x 0.6 x 0.1 cm). No possible lymph nodes are identified. The specimen is submitted entirely in D.
- (E) LEFT BASE – Supplemental report to follow.
- (F) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer

SNOMED CODES

T-C4600, M-00110

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by:

These tests have not been

[page 2 of 4]
[REDACTED]

Specimen Date/Time:

Start of ADDENDUM

[page 3 of 4]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(E) LEFT BASE:

Fibromuscular tissue and fibroadipose tissue with vessels, nerve trunks and ganglia consistent with extraprostatic tissue/superior neurovascular bundle tissue and bladder neck tissue and minute focus of prostate glands, no tumor present.

(F) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 7 (4 + 3). (SEE COMMENT)

TUMOR EXTENDING INTO EXTRAPROSTATIC TISSUE.

Margins of resection, free of tumor.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

PERINEURAL INVASION, PRESENT.

No lymphovascular invasion identified.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma. Both tumor foci are located in the peripheral zone. The dominant tumor focus is located in the right lateral, right posterolateral and right posterior peripheral zone. This tumor focus measures 2.0 x 1.0 cm in the largest cross-sectional dimension and it is present in the single cross section of the prostate and extensively in the apex and base. In the right superior neurovascular bundle region, this tumor focus extends focally into extraprostatic tissue. The added length of extraprostatic extension is 2.0 mm. The margins of resection are free of tumor. The second tumor focus is located in the left lateral and left posterolateral peripheral zone. This tumor focus measures 1.0 x 0.4 cm in the largest cross-sectional dimension and it is present in the single cross section of the prostate and focally in the apex and base. This tumor focus is of lower histologic grade and confined to the prostate with negative margins.

GROSS DESCRIPTION

(E) LEFT BASE – A fragment of tan-gray tissue measuring 1.5 x 0.4 x 0.3 cm. No orientation provided. Submitted in E.

(F) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.6 x 2.2 x 2.7 cm, 21 grams, post fixation) has the usual shape. The soft tissue present along the posterolateral aspects of the prostate is scant and symmetrical. A firm nodule is present on the right base of the prostate. Serial cross sections after fixation do not demonstrate unequivocal carcinoma.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

Also included in the container is a detached fragment of tissue consistent with seminal vesicle measuring 1.8 x 1.2 x 0.5

[page 4 of 4]
Specimen Date/Time:

cm.

SECTION CODE: F1, detached fragment of seminal vesicle; F2-F5, right seminal vesicle and segment of right vas deferens from the base towards the tip; F6-F8, left seminal vesicle and segment of left vas deferens from the base towards the tip; F9, prostatic base, right border; F10, prostatic base, right posterior border; F11-F15, prostatic base, central portion; prostatic base, left border; F17-F18, prostatic base, left posterior border; F19, F20, apex anterior; F21, F22, apex left; F23, F24, apex posterior; F25, F26, apex right; F27-F30, sections of the single cross section of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (F17, F18 and F23) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

T-72000, M-Y1973

Entire report and diagnosis completed by:

-----END OF REPORT-----

Diagnostic Discrepancy	10/23/13	/
HR/AA Discrepancy		/
Proximal Margin History		/

Source: NCI Genomic Data Commons file 165157f1-4dfe-42a5-83fc-a573cc0f55cf (TCGA-KK-A8I6.11107580-AAF3-4CE8-AC75-8636CE8C515E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).